Somatic mutation profile of tumor specimen TCGA-FG-7643-01A (aliquot TCGA-FG-7643-01A-11D-2086-08) from TCGA case TCGA-FG-7643, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 49.8 years (18,206 days).
Specimen TCGA-FG-7643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7603de2f-ffc4-4c2b-be3d-f2cab6a3a90d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7643-10A (Blood Derived Normal), aliquot TCGA-FG-7643-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8870b557-6f42-40a0-87d6-69da5e25f4d5

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 3, Frame Shift Ins 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.15299G>T p.R5100M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV67997176; called by muse, mutect2
- C3orf14 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs780990044, COSV51707817; called by muse, mutect2, varscan2
- C7 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs977205539, COSV57471561; called by muse, mutect2, varscan2
- CACNA1S | c.4015G>A p.D1339N | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV62945037; called by muse, mutect2
- CFAP45 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371893609; called by muse, mutect2, varscan2
- CXCR1 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs745619216, COSV55282693; called by muse, mutect2
- CYYR1 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54839124; called by muse, mutect2
- DIAPH1 | c.2773G>A p.V925M | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773243948, COSV53889475; called by muse, mutect2, varscan2
- EBF3 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62480615, COSV62483216; called by muse, mutect2, varscan2
- EPHA6 | c.2539T>C p.Y847H (on ENST00000389672 / NM_001080448.3; = p.Y239H on NM_173655.4) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67598526; called by muse, mutect2
- FAM71B | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | catalogued as rs778276804, COSV57227961; called by muse, mutect2, varscan2
- GARS1 | c.978T>G p.I326M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443380634, COSV66829569; called by muse, mutect2
- GRIN2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV74206768; called by muse, mutect2
- HMCN1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs770643584, COSV54950636; called by muse, mutect2, varscan2
- IL16 | c.2773C>G p.P925A (on ENST00000302987 / NM_172217.5; = p.P224A on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs762035180, COSV57269348; called by muse, mutect2, varscan2
- KIF13B | c.3305G>A p.R1102H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778060352, COSV72954781; called by muse, mutect2, varscan2
- KLHL8 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532263956, COSV56750130; called by muse, mutect2
- KRT27 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs377315465, COSV56973874; called by muse, mutect2, varscan2
- LTBP2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs762006320, COSV56210216; called by muse, mutect2
- MAGI2 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV62706563; called by muse, mutect2
- NLRP6 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV56459139; called by muse, mutect2, varscan2
- OR52M1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs779642009, COSV100798587, COSV64172039; called by muse, mutect2, varscan2
- PCDHB8 | c.765C>G p.D255E | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV50831672; called by muse, mutect2, varscan2
- POLR2B | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.271); catalogued as COSV58903393; called by muse, mutect2, varscan2
- ROM1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 21/129 reads (16%) | catalogued as rs1242900857, COSV53884974, COSV99606045; called by muse, mutect2, varscan2
- ROS1 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as rs772772410, COSV100877724, COSV63852375; called by muse, mutect2, varscan2
- RP1 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55129422; called by muse, mutect2
- RTKN2 | c.1666A>G p.M556V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs779695465, COSV59525076; called by muse, mutect2, varscan2
- SLCO6A1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs539137924, COSV65805537; called by muse, mutect2
- SPINK5 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs780631964, COSV56264284; called by muse, mutect2, varscan2
- TMEM151A | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs986990494, COSV59175715; called by muse, mutect2
- TRIM60 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV61972030; called by muse, mutect2
- ZSWIM2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200253183; called by muse, mutect2, varscan2
- PDE12 | c.651dup p.P218Sfs*10 | Frame Shift Ins (INS) | VAF 35/276 reads (13%) | called by mutect2, pindel, varscan2
- PI4KB | c.2351dup p.L785Afs*22 (on ENST00000368873 / NM_001369623.1; = p.L797Afs*22 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- CCDC158 | c.2679T>A p.A893= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV66357421; called by muse, mutect2
- CDSN | c.1440C>T p.S480= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1382345000, COSV52537639; called by muse, mutect2, varscan2
- CFAP54 | c.6063G>A p.L2021= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV61576170; called by muse, mutect2, varscan2
- EGR1 | c.1587G>A p.S529= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as COSV53518117; called by muse, mutect2, varscan2
- GABRG1 | c.703T>C p.L235= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV54963389; called by muse, mutect2, varscan2
- MAP3K3 | c.759C>T p.D253= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs773871394, COSV62282174; called by muse, mutect2, varscan2
- OR5D18 | c.381T>A p.I127= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV61739089; called by muse, mutect2, varscan2
- PCDHGC4 | c.1104G>A p.V368= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs1156704202, COSV52768147, COSV99341066; called by muse, mutect2, varscan2
- TAS2R8 | c.159C>T p.I53= | Silent (SNP) | VAF 24/190 reads (13%) | catalogued as rs776855827, COSV53691209, COSV99554004; called by muse, mutect2, varscan2
- WDR1 | c.1791C>T p.A597= (on ENST00000382452; = p.A457= on NM_005112.5) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV66727144; called by muse, mutect2, varscan2
- ZNF831 | c.720C>T p.G240= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs747918771, COSV64041504; called by muse, mutect2, varscan2
- AC073310.1 | n.696G>T | RNA (SNP) | VAF 19/136 reads (14%) | catalogued as rs760470851; called by muse, mutect2, varscan2
- C15orf54 | n.420G>A | RNA (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- CPLANE1 | chr5:37169083 T>C | 3'Flank (SNP) | VAF 13/123 reads (11%) | catalogued as COSV57077371; called by muse, mutect2, varscan2
